Somatic mutation profile of tumor specimen C3L-02465-02 (aliquot CPT0125570009) from CPTAC case C3L-02465, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 50.6 years (18,464 days).
Specimen C3L-02465-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f0523bc-5b0e-42f0-9c50-b5d084884bf2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02465-31 (Blood Derived Normal), aliquot CPT0124250002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/348bf501-a6a1-4c39-8bd6-1c9e8914fc33

The open-access MAF lists 56 somatic variants for this specimen: 40 protein-altering or splice-affecting, 11 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 11, Frame Shift Del 2, 3'UTR 2, Splice Region 1, RNA 1, Nonsense Mutation 1, Splice Site 1, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1810T>C p.C604R | Missense Mutation (SNP) | VAF 25/107 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV55888333; called by muse, mutect2, varscan2
- TP53 | c.589G>A p.V197M | Missense Mutation (SNP) | VAF 106/393 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as rs786204041, CM070297, COSV52711079, COSV52927251, COSV53163944; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AC092718.8 | c.274A>G p.T92A | Missense Mutation (SNP) | VAF 26/285 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.087); catalogued as rs1022460642; called by muse, mutect2
- C6 | c.2653C>T p.P885S | Missense Mutation (SNP) | VAF 53/339 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs1434921124; called by muse, varscan2
- CATSPER1 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 58/311 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs372082637; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CFAP299 | c.287C>T p.T96M | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as rs142731425; called by muse, mutect2
- CHADL | c.1489C>T p.P497S | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1217406159, COSV99346592; called by muse, mutect2, varscan2
- CSMD3 | c.4113C>A p.H1371Q (on ENST00000297405 / NM_001363185.1; = p.H1267Q on NM_052900.3) | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99831367; called by muse, mutect2, varscan2
- DCAF4 | c.185C>T p.S62F | Missense Mutation (SNP) | VAF 45/89 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs1567304591, COSV100611164; called by muse, mutect2, varscan2
- FAM120A | c.2101G>A p.A701T | Missense Mutation (SNP) | VAF 26/262 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.113); catalogued as COSV52909967; called by muse, mutect2
- GRIN2B | c.569T>C p.I190T | Missense Mutation (SNP) | VAF 54/192 reads (28%) | SIFT tolerated (0.9); PolyPhen possibly damaging (0.865); catalogued as COSV101663146; called by muse, mutect2, varscan2
- KCNB2 | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV101578670; called by muse, mutect2, varscan2
- MYLK | c.4504G>A p.E1502K | Missense Mutation (SNP) | VAF 87/427 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as COSV60605650; called by muse, mutect2, varscan2
- OR6K3 | c.827G>A p.R276H (on ENST00000368146; = p.R260H on NM_001005327.2) | Missense Mutation (SNP) | VAF 58/226 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.344); catalogued as rs145239299; called by muse, mutect2, varscan2
- PNPLA8 | c.1693G>C p.V565L | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.249); catalogued as rs1167576062, COSV99993560; called by muse, mutect2, varscan2
- RYR3 | c.9002C>T p.T3001M (on ENST00000389232; = p.T3002M on NM_001036.6) | Missense Mutation (SNP) | VAF 40/215 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs776121340, COSV66777565; called by muse, mutect2, varscan2
- SLC25A31 | c.841T>C p.F281L | Missense Mutation (SNP) | VAF 35/213 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as rs144417673; called by muse, mutect2, varscan2
- TMEM63A | c.2086G>A p.A696T | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376648031; called by muse, mutect2, varscan2
- TOGARAM2 | c.2542A>G p.I848V | Missense Mutation (SNP) | VAF 58/401 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs183105380; called by muse, mutect2, varscan2
- TRPM3 | c.2515C>T p.R839* (on ENST00000357533 / NM_001366142.2; = p.R682* on NM_020952.6) | Nonsense Mutation (SNP) | VAF 19/89 reads (21%) | catalogued as rs777039638, CM142979, COSV62581909; called by muse, mutect2, varscan2
- TTN | c.34313C>T p.P11438L (on ENST00000591111; = p.P12501L on NM_001267550.2) | Missense Mutation (SNP) | VAF 17/129 reads (13%) | PolyPhen benign (0); catalogued as rs1236045684; ClinVar: uncertain significance; called by mutect2, varscan2
- ATCAY | c.745T>A p.W249R | Missense Mutation (SNP) | VAF 25/247 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BICDL2 | c.1054C>G p.P352A | Missense Mutation (SNP) | VAF 56/272 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- C2orf16 | c.669G>T p.Q223H | Missense Mutation (SNP) | VAF 35/190 reads (18%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- DLX5 | c.143A>G p.Y48C | Missense Mutation (SNP) | VAF 38/227 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNHD1 | c.10915_10919del p.E3639Rfs*15 | Frame Shift Del (DEL) | VAF 73/377 reads (19%) | called by mutect2, pindel, varscan2
- FRYL | c.7985C>T p.P2662L | Missense Mutation (SNP) | VAF 21/230 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IDUA | c.793-5C>A | Splice Region (SNP) | VAF 27/166 reads (16%) | called by muse, mutect2, varscan2
- KIF15 | c.820G>T p.D274Y | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- LBR | c.475A>G p.S159G | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRFN1 | c.206A>G p.E69G | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NLRP1 | c.4208T>A p.L1403Q (on ENST00000572272 / NM_033004.4; = p.L1359Q on NM_014922.5) | Missense Mutation (SNP) | VAF 87/355 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRRT3 | c.2173G>A p.G725R | Missense Mutation (SNP) | VAF 38/173 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- RGS9BP | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2
- SETD2 | c.1771_1775del p.Q591Tfs*6 | Frame Shift Del (DEL) | VAF 17/88 reads (19%) | called by mutect2, pindel, varscan2
- SPDYE4 | c.514A>C p.N172H | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- TENT2 | c.368C>T p.T123I | Missense Mutation (SNP) | VAF 38/206 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TERT | c.677G>T p.G226V | Missense Mutation (SNP) | VAF 9/216 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.154); called by muse, mutect2
- TG | c.8194G>A p.A2732T | Missense Mutation (SNP) | VAF 88/333 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- USP5 | c.1496_1498+14del p.X499_splice | Splice Site (DEL) | VAF 12/87 reads (14%) | called by mutect2, pindel
- ACTL6B | c.222G>A p.V74= | Silent (SNP) | VAF 43/269 reads (16%) | called by muse, mutect2, varscan2
- CHAT | c.1068C>T p.D356= | Silent (SNP) | VAF 57/225 reads (25%) | catalogued as rs748193892, COSV60320071; ClinVar: likely benign; called by muse, mutect2, varscan2
- CHRNA7 | c.1143C>T p.N381= | Silent (SNP) | VAF 76/650 reads (12%) | catalogued as rs542404300, COSV60967848; called by muse, mutect2, varscan2
- CKAP5 | c.5187A>G p.L1729= (on ENST00000529230 / NM_001008938.4; = p.L1669= on NM_014756.3) | Silent (SNP) | VAF 15/80 reads (19%) | called by muse, mutect2, varscan2
- COL6A6 | c.4269C>T p.I1423= | Silent (SNP) | VAF 59/265 reads (22%) | catalogued as rs375056319; called by muse, mutect2, varscan2
- CRTAP | c.601C>T p.L201= | Silent (SNP) | VAF 44/282 reads (16%) | called by muse, mutect2, varscan2
- DNAH3 | c.7365A>G p.L2455= | Silent (SNP) | VAF 42/235 reads (18%) | called by muse, mutect2, varscan2
- MAN1C1 | c.240G>A p.P80= | Silent (SNP) | VAF 25/179 reads (14%) | catalogued as rs1241820810; called by muse, mutect2, varscan2
- PLCH2 | c.1017G>A p.S339= | Silent (SNP) | VAF 69/368 reads (19%) | catalogued as rs143425245; called by muse, mutect2, varscan2
- PRAMEF15 | c.1059C>A p.T353= | Silent (SNP) | VAF 85/829 reads (10%) | called by muse, mutect2, varscan2
- SMPDL3B | c.885C>T p.S295= | Silent (SNP) | VAF 41/161 reads (25%) | catalogued as rs1185586749, COSV65855061; called by muse, mutect2, varscan2
- AC093791.1 | n.389C>T | RNA (SNP) | VAF 5/21 reads (24%) | catalogued as rs1224136390; called by muse, mutect2
- KCNJ11 | c.*29G>A | 3'UTR (SNP) | VAF 6/28 reads (21%) | catalogued as rs370047076; called by muse, mutect2, varscan2
- MARVELD3 | chr16:71640676 G>A | 3'Flank (SNP) | VAF 75/314 reads (24%) | catalogued as rs763430420; called by muse, mutect2, varscan2
- PACS2 | c.207+20C>G | Intron (SNP) | VAF 92/215 reads (43%) | catalogued as rs375542895; called by muse, mutect2, varscan2
- SULF1 | c.*760C>T | 3'UTR (SNP) | VAF 9/57 reads (16%) | catalogued as rs1335374587; called by muse, mutect2, varscan2
